Gene-level copy-number profile of tumor specimen TCGA-HT-7475-01A from TCGA case TCGA-HT-7475, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 67.6 years (24,686 days).
Specimen TCGA-HT-7475-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.762face3-cefa-45bb-8698-b702aaa3af5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HT-7475-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0afd8103-19d5-4845-806b-a04411788dc5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,187; copy number 2: 46,268; copy number 3: 3,562; copy number 4: 2; copy number 5: 217; copy number 6: 1,438; copy number 7: 143.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HT-7475-01A-11D-2023-01): tumor purity 0.84, ploidy 2.03, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,798 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:84,847,877–148,420,998, 1,230 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr8:107,173,200–145,066,685, 568 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,806. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
